Somatic mutation profile of tumor specimen TARGET-20-PANTWV-09A (aliquot TARGET-20-PANTWV-09A-01D) from TARGET case TARGET-20-PANTWV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,230 days).
Specimen TARGET-20-PANTWV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c47f7312-3beb-4627-8104-c55a3e35ac49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANTWV-14A (Bone Marrow Normal), aliquot TARGET-20-PANTWV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01402468-021e-4146-9b08-1df7223a39c2

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 115/242 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RUSC1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs747363737; called by muse, mutect2, varscan2
- NRG1 | c.1891G>A p.V631I (on ENST00000405005 / NM_013964.5; = p.V636I on NM_013956.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEC24B | c.1166-1G>A p.X389_splice | Splice Site (SNP) | VAF 124/295 reads (42%) | called by muse, mutect2, varscan2
- TRPM7 | c.5309G>A p.G1770D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF5B | c.3546T>C p.L1182= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs1412682971; called by muse, mutect2, varscan2
- PLEKHD1 | c.633G>A p.E211= | Silent (SNP) | VAF 89/211 reads (42%) | called by muse, mutect2, varscan2
- SLC9A5 | c.219G>T p.L73= | Silent (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-68A>G | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
